Somatic mutation profile of tumor specimen MMRF_1331_1_BM_CD138pos (aliquot MMRF_1331_1_BM_CD138pos_T1_KAS5U_L01219) from MMRF case MMRF_1331, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.1 years (24,883 days).
Specimen MMRF_1331_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9abea60e-7b02-4c1c-aeb5-25bc036de78e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1331_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1331_1_PB_Whole_C2_KAS5U_L01230; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d83ae081-a47e-4155-9643-2783cb30ecf1

The open-access MAF lists 98 somatic variants for this specimen: 41 protein-altering or splice-affecting, 12 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 26, Intron 12, Silent 12, Nonsense Mutation 4, 5'Flank 4, Frame Shift Del 1, In Frame Ins 1, RNA 1, In Frame Del 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADH4 | c.146C>G p.T49S | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.098); catalogued as rs765350444; called by muse, mutect2, varscan2
- ASF1B | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs764132488; called by muse, mutect2, varscan2
- ATF3 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.634); catalogued as rs1389773222; called by muse, mutect2, varscan2
- DYNC2H1 | c.12752G>A p.G4251D | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV62099613; called by muse, mutect2, varscan2
- GIMAP8 | c.25T>C p.S9P | Missense Mutation (SNP) | VAF 78/137 reads (57%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs746636931; called by muse, mutect2, varscan2
- IGBP1P2 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs773767279; called by muse, mutect2, varscan2
- IGHV1-69D | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 32/63 reads (51%) | catalogued as rs1387568701; called by muse, mutect2, varscan2
- IGHV2-70 | c.161G>A p.C54Y | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368641348; called by muse, varscan2
- IGKJ3 | c.25A>T p.K9* | Nonsense Mutation (SNP) | VAF 47/50 reads (94%) | catalogued as rs181878952; called by muse, varscan2
- IGKV4-1 | c.150A>C p.L50F | Missense Mutation (SNP) | VAF 53/54 reads (98%) | SIFT tolerated (0.16); PolyPhen benign (0.087); catalogued as rs372543667; called by muse, varscan2
- MYOC | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs766083192, COSV50673903, COSV50674762, COSV50680547; called by muse, mutect2, varscan2
- OR8H1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 102/170 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100477006; called by muse, mutect2, varscan2
- PGLYRP2 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52996641; called by muse, mutect2
- RPTN | c.298del p.Q100Sfs*111 | Frame Shift Del (DEL) | VAF 62/172 reads (36%) | catalogued as COSV60168603; called by mutect2, pindel, varscan2
- SLC26A9 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs768527846, COSV61606068; called by muse, mutect2, varscan2
- ABCA12 | c.2260A>G p.T754A (on ENST00000272895 / NM_173076.3; = p.T436A on NM_015657.3) | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ANXA4 | c.186_187insTGTCTCTCC p.I62_G63insCLS | In Frame Ins (INS) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- BCL6 | c.1916T>C p.F639S | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C14orf39 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2
- C16orf70 | c.1053G>A p.W351* | Nonsense Mutation (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
- CDC42BPB | c.1733C>T p.S578L | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- COL2A1 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CRISP1 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- CSMD1 | c.8977A>T p.S2993C (on ENST00000520002; = p.S2992C on NM_033225.6) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CYFIP2 | c.3371T>C p.I1124T (on ENST00000616178 / NM_001291722.2; = p.I1099T on NM_014376.4) | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- FBXL15 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- GOLGA2 | c.1018-6A>T | Splice Region (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- GOLGA7 | c.264+1G>A p.X88_splice | Splice Site (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- HEG1 | c.2390G>A p.S797N | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MCM6 | c.974T>C p.I325T | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.339); called by muse, varscan2
- NOP56 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OSBP | c.1050G>T p.M350I | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN6 | c.1445T>C p.I482T | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RAB32 | c.402C>A p.S134R | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RPRD1B | c.695A>C p.E232A | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- RYBP | c.216_233del p.E72_Q77del | In Frame Del (DEL) | VAF 14/75 reads (19%) | called by mutect2, pindel, varscan2
- STT3A | c.2107T>C p.S703P | Missense Mutation (SNP) | VAF 86/226 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- TKFC | c.742A>T p.T248S | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF516 | c.2047G>C p.E683Q | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ZNF75A | c.113T>A p.L38H | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, varscan2
- ZNF841 | c.1403T>A p.L468Q (on ENST00000426391 / NM_001369830.1; = p.L584Q on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CDK20 | c.954C>A p.P318= (on ENST00000325303 / NM_001039803.3; = p.P297= on NM_012119.4) | Silent (SNP) | VAF 65/106 reads (61%) | catalogued as rs374163052; called by muse, mutect2, varscan2
- FGFR2 | c.2085G>A p.E695= | Silent (SNP) | VAF 49/96 reads (51%) | catalogued as rs1429713025; called by muse, mutect2, varscan2
- GPR156 | c.2151A>G p.S717= | Silent (SNP) | VAF 47/138 reads (34%) | called by muse, mutect2, varscan2
- GRM5 | c.1096C>A p.R366= | Silent (SNP) | VAF 60/90 reads (67%) | called by muse, mutect2, varscan2
- IGHJ3 | c.6T>G p.A2= | Silent (SNP) | VAF 20/22 reads (91%) | catalogued as rs781789998; called by muse, mutect2
- IGHV2-70D | c.168C>T p.S56= | Silent (SNP) | VAF 32/33 reads (97%) | catalogued as rs1233195687; called by muse, varscan2
- KLK15 | c.633A>G p.G211= | Silent (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2
- MYL4 | c.150C>A p.A50= | Silent (SNP) | VAF 43/79 reads (54%) | called by muse, mutect2, varscan2
- NCS1 | c.495C>T p.T165= | Silent (SNP) | VAF 33/100 reads (33%) | called by muse, mutect2, varscan2
- OTUD7A | c.2592C>T p.A864= (on ENST00000307050 / NM_001382637.1; = p.A857= on NM_130901.3) | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs535629817; called by muse, mutect2, varscan2
- TTN | c.22689T>C p.S7563= (on ENST00000591111; = p.S6636= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- ZNF648 | c.819C>T p.G273= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs569577539; called by muse, mutect2, varscan2
- AC092718.3 | c.*156C>T | 3'UTR (SNP) | VAF 54/111 reads (49%) | catalogued as rs113609400, COSV66112904; called by muse, mutect2, varscan2
- ATP5F1AP2 | n.364A>G | RNA (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021476 G>C | 5'Flank (SNP) | VAF 39/81 reads (48%) | called by muse, mutect2, varscan2
- CD93 | c.*2872A>T | 3'UTR (SNP) | VAF 31/56 reads (55%) | called by muse, mutect2, varscan2
- CEMIP2 | c.*1610T>G | 3'UTR (SNP) | VAF 19/38 reads (50%) | called by muse, varscan2
- CPLX4 | c.*900del | 3'UTR (DEL) | VAF 16/30 reads (53%) | catalogued as rs959471921; called by mutect2, varscan2
- CRB1 | c.3878+1229G>A | Intron (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- DIO3 | chr14:101557619 del A | 5'Flank (DEL) | VAF 25/73 reads (34%) | called by mutect2, pindel, varscan2
- DPP10 | chr2:114442496 T>G | 5'Flank (SNP) | VAF 10/27 reads (37%) | called by muse, varscan2
- DSC1 | c.2488-253A>T | Intron (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2, varscan2
- DUSP6 | chr12:89352928 C>A | 5'Flank (SNP) | VAF 39/72 reads (54%) | called by muse, mutect2, varscan2
- FAM167A | c.*2518G>C | 3'UTR (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- FAM53B | c.*3808T>C | 3'UTR (SNP) | VAF 32/84 reads (38%) | called by muse, mutect2, varscan2
- FGD4 | c.*3058T>A | 3'UTR (SNP) | VAF 36/69 reads (52%) | catalogued as rs552637454; called by muse, mutect2, varscan2
- FLT4 | c.3807+67C>T | Intron (SNP) | VAF 5/24 reads (21%) | catalogued as rs1251785870; called by muse, varscan2
- FOXP1 | c.*893G>A | 3'UTR (SNP) | VAF 39/171 reads (23%) | catalogued as rs1165236490; called by muse, mutect2, varscan2
- GALNT15 | c.*912G>A | 3'UTR (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- GAREM1 | c.*1173T>C | 3'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- GRIK3 | c.*4402C>T | 3'UTR (SNP) | VAF 37/66 reads (56%) | called by muse, mutect2, varscan2
- GULP1 | c.844-523A>C | Intron (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- IGFBP2 | c.813+80G>A | Intron (SNP) | VAF 7/17 reads (41%) | catalogued as rs576385155; called by muse, mutect2, varscan2
- ILDR2 | c.*38A>C | 3'UTR (SNP) | VAF 42/102 reads (41%) | called by muse, mutect2, varscan2
- KLF7 | c.*5849T>A | 3'UTR (SNP) | VAF 16/28 reads (57%) | catalogued as rs973513897, COSV58746863; called by muse, mutect2, varscan2
- KLHDC4 | c.507-134T>A | Intron (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2
- METTL6 | c.*305C>T | 3'UTR (SNP) | VAF 56/82 reads (68%) | called by muse, mutect2, varscan2
- MRTO4 | c.*1003T>G | 3'UTR (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- NSFL1C | c.*1275C>G | 3'UTR (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- NWD2 | c.-150C>T | 5'UTR (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- OR2L13 | c.*83C>A | 3'UTR (SNP) | VAF 43/91 reads (47%) | called by muse, mutect2, varscan2
- PDE4DIP | c.2815+2787G>A | Intron (SNP) | VAF 72/148 reads (49%) | called by muse, mutect2, varscan2
- PKNOX2 | c.*174C>T | 3'UTR (SNP) | VAF 54/222 reads (24%) | catalogued as rs182170552; called by muse, mutect2, varscan2
- PRKAR2A | c.*4697T>G | 3'UTR (SNP) | VAF 54/90 reads (60%) | called by muse, mutect2, varscan2
- PRKN | c.*226T>C | 3'UTR (SNP) | VAF 28/42 reads (67%) | called by muse, mutect2, varscan2
- RPL36A | c.3+107A>C | Intron (SNP) | VAF 34/35 reads (97%) | called by muse, mutect2, varscan2
- SAMD5 | c.*3060T>C | 3'UTR (SNP) | VAF 24/28 reads (86%) | called by muse, mutect2, varscan2
- SCAF8 | c.*315C>A | 3'UTR (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- SEPTIN9 | c.722-36958G>A | Intron (SNP) | VAF 40/82 reads (49%) | called by muse, mutect2, varscan2
- TAB1 | c.*299C>T | 3'UTR (SNP) | VAF 48/99 reads (48%) | catalogued as rs1205197102; called by muse, mutect2, varscan2
- TAFA5 | c.112+54946C>T | Intron (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- TDP1 | c.*1562G>A | 3'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- THRB | c.*4358del | 3'UTR (DEL) | VAF 61/94 reads (65%) | called by mutect2, varscan2
- TP53AIP1 | c.141+276_141+279del | Intron (DEL) | VAF 12/18 reads (67%) | called by mutect2, varscan2
- UNCX | c.*318C>A | 3'UTR (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- ZNF528 | chr19:52418403 T>G | 3'Flank (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- ZNF75A | c.101-67T>A | Intron (SNP) | VAF 18/40 reads (45%) | called by muse, varscan2
